Somatic mutation profile of tumor specimen TCGA-VS-A9UI-01A (aliquot TCGA-VS-A9UI-01A-11D-A42O-09) from TCGA case TCGA-VS-A9UI, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIB; Tumor grade: GX; Age at diagnosis: 76.2 years (27,838 days).
Specimen TCGA-VS-A9UI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 800867a7-6a4c-43ea-a66b-676de99e5a39.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VS-A9UI-10A (Blood Derived Normal), aliquot TCGA-VS-A9UI-10A-01D-A42R-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/147a8d8a-07de-47fc-ad97-dd41b7895583

The open-access MAF lists 145 somatic variants for this specimen: 98 protein-altering or splice-affecting, 43 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 86, Silent 43, Nonsense Mutation 8, 3'UTR 2, Splice Region 2, In Frame Del 1, Intron 1, Splice Site 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGG | c.902G>A p.R301H | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913088, CM950480, COSV60196181; ClinVar: other / pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 29/110 reads (26%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABR | c.2293C>T p.P765S (on ENST00000302538 / NM_021962.5; = p.P728S on NM_001092.5) | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs866805902; called by muse, mutect2
- ACAD11 | c.769C>T p.H257Y | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.019); catalogued as rs1356472776, COSV53902061; called by muse, mutect2, varscan2
- AHNAK2 | c.7483G>T p.V2495L | Missense Mutation (SNP) | VAF 31/124 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0.168); catalogued as rs372112311, COSV100317904; called by muse, mutect2, varscan2
- AKNAD1 | c.320C>T p.S107L | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as rs763755230, COSV100645629; called by muse, mutect2, varscan2
- APBA2 | c.415G>A p.E139K | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.604); catalogued as COSV101382300; called by muse, mutect2, varscan2
- APOB | c.11108G>A p.R3703H | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as rs1414976234, COSV51956399; called by muse, mutect2, varscan2
- ARHGAP32 | c.4063G>A p.D1355N (on ENST00000310343 / NM_001378025.1; = p.D1006N on NM_014715.4) | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.025); catalogued as COSV100088101; called by muse, mutect2, varscan2
- ATP10D | c.74C>T p.S25L | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV99905737; called by muse, mutect2, varscan2
- ATP2A1 | c.157G>C p.V53L | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV100837313; called by muse, mutect2, varscan2
- C17orf58 | c.122T>C p.M41T | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as COSV100558732; called by muse, mutect2, varscan2
- CACHD1 | c.727C>T p.Q243* | Nonsense Mutation (SNP) | VAF 16/74 reads (22%) | catalogued as COSV99262559; called by muse, mutect2, varscan2
- CASQ1 | c.577C>T p.H193Y | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.39); PolyPhen benign (0.091); catalogued as rs760302092, COSV100927315; called by muse, mutect2, varscan2
- CASQ1 | c.613C>T p.H205Y | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV63624313; called by muse, mutect2, varscan2
- CASS4 | c.376C>T p.P126S | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as COSV100824757; called by muse, mutect2, varscan2
- CBLB | c.1613G>A p.R538K | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV99913639; called by muse, mutect2, varscan2
- CCDC136 | c.559C>T p.R187C | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); catalogued as rs142162337; called by muse, mutect2, varscan2
- CCDC33 | c.589A>T p.N197Y | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.461); catalogued as COSV100351494; called by muse, mutect2, varscan2
- CDH7 | c.1441G>A p.E481K | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.078); catalogued as COSV100542597; called by muse, mutect2, varscan2
- CLPB | c.730G>A p.A244T | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0); catalogued as rs1388099196, COSV53633058; called by muse, mutect2, varscan2
- CNGB1 | c.919G>C p.E307Q | Missense Mutation (SNP) | VAF 4/70 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.141); catalogued as COSV99203133; called by muse, mutect2
- COL6A2 | c.1018G>A p.G340R | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56007190; called by muse, mutect2, varscan2
- DAP3 | c.175C>T p.H59Y | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs759970366, COSV100546563; called by muse, mutect2, varscan2
- DCHS1 | c.2486C>T p.S829L | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.985); catalogued as rs1275052575, COSV100202187; called by muse, mutect2, varscan2
- DLG2 | c.1252G>C p.E418Q | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.54); catalogued as COSV54670749, COSV99716922; called by muse, mutect2, varscan2
- DNAH2 | c.5050A>T p.K1684* | Nonsense Mutation (SNP) | VAF 9/17 reads (53%) | catalogued as COSV101209433; called by muse, mutect2, varscan2
- EFL1 | c.1607G>A p.R536Q | Missense Mutation (SNP) | VAF 33/123 reads (27%) | SIFT tolerated (0.94); PolyPhen benign (0.003); catalogued as rs372161887; called by muse, mutect2, varscan2
- EIPR1 | c.4G>C p.E2Q | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.261); catalogued as COSV100160648; called by muse, mutect2
- FLG | c.5177C>G p.S1726* | Nonsense Mutation (SNP) | VAF 22/125 reads (18%) | catalogued as COSV100911675, COSV100911911; called by muse, mutect2, varscan2
- FLG2 | c.4538G>T p.G1513V | Missense Mutation (SNP) | VAF 16/119 reads (13%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV101165951, COSV66171314; called by muse, mutect2, varscan2
- FSTL1 | c.688G>C p.E230Q | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.167); catalogued as COSV55235033; called by muse, mutect2, varscan2
- GABRR3 | c.452G>A p.R151K | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT tolerated (0.45); PolyPhen benign (0.329); catalogued as COSV72083959; called by muse, mutect2, varscan2
- GTPBP1 | c.131C>A p.S44* | Nonsense Mutation (SNP) | VAF 7/20 reads (35%) | catalogued as COSV99323274; called by muse, mutect2, varscan2
- HERC2 | c.10379G>C p.R3460T | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.59); PolyPhen benign (0.056); catalogued as rs1438915407, COSV99874636; called by muse, mutect2, varscan2
- HYDIN | c.5789-1G>A p.X1930_splice | Splice Site (SNP) | VAF 4/24 reads (17%) | catalogued as COSV99993109; called by mutect2, varscan2
- IVNS1ABP | c.1696G>A p.G566S | Missense Mutation (SNP) | VAF 10/146 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100832774; called by muse, mutect2
- KCNH1 | c.2794G>A p.E932K (on ENST00000271751 / NM_172362.3; = p.E905K on NM_002238.4) | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.796); catalogued as rs370643808; called by muse, mutect2, varscan2
- KCNV2 | c.855G>A p.M285I | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs768649666, COSV101172612; called by muse, mutect2, varscan2
- KNDC1 | c.4141G>A p.G1381S | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.44); PolyPhen benign (0.005); catalogued as rs773807341, COSV100465233, COSV58831454; called by muse, mutect2, varscan2
- KRT16 | c.1124T>A p.I375N | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100052953; called by muse, mutect2, varscan2
- LBHD1 | c.514G>A p.E172K (on ENST00000431002 / NM_001367940.1; = p.E146K on NM_024099.3) | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.792); catalogued as COSV100649164; called by muse, mutect2, varscan2
- LCK | c.821G>A p.S274N | Missense Mutation (SNP) | VAF 33/105 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV100287777; called by muse, mutect2, varscan2
- LMX1A | c.118C>T p.R40W | Missense Mutation (SNP) | VAF 20/107 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs139738225, COSV99672509; called by muse, mutect2, varscan2
- LRRC7 | c.562C>A p.L188I (on ENST00000651989 / NM_001370785.2; = p.L155I on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as COSV99227687; called by muse, mutect2, varscan2
- LY9 | c.1192C>T p.P398S | Missense Mutation (SNP) | VAF 32/52 reads (62%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.961); catalogued as rs755109796, COSV54431664; called by muse, mutect2, varscan2
- MAP1A | c.4546G>A p.A1516T | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as rs748878166, COSV55808318; called by muse, mutect2, varscan2
- MFAP3L | c.675C>G p.F225L | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV64372017; called by muse, mutect2, varscan2
- MGAT4C | c.728C>T p.S243F | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs199811466, COSV100153049; called by muse, mutect2, varscan2
- MICU1 | c.775C>T p.R259C (on ENST00000361114 / NM_001195518.2; = p.R265C on NM_006077.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs367648335; called by muse, mutect2, varscan2
- MTTP | c.781A>G p.T261A | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.011); catalogued as COSV99645288; called by muse, mutect2, varscan2
- MYCN | c.1222G>A p.V408M | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV55258035; called by muse, mutect2, varscan2
- NKTR | c.2891G>T p.C964F | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0); catalogued as COSV51774183; called by muse, mutect2, varscan2
- NLRP3 | c.2734C>T p.L912F | Missense Mutation (SNP) | VAF 29/117 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.404); catalogued as COSV100276230, COSV60222745; called by muse, mutect2, varscan2
- OSBPL3 | c.2442G>A p.Q814= | Splice Region (SNP) | VAF 15/59 reads (25%) | catalogued as COSV100514241; called by muse, mutect2, varscan2
- PCDHGB7 | c.421G>C p.E141Q | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT tolerated (0.31); PolyPhen benign (0.05); catalogued as COSV99540457; called by muse, mutect2
- PCLO | c.7472C>T p.S2491F | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.667); catalogued as COSV100433786; called by muse, mutect2, varscan2
- PCOLCE2 | c.368T>G p.M123R | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.222); catalogued as COSV99930754; called by muse, mutect2, varscan2
- PCP2 | c.346C>T p.Q116* | Nonsense Mutation (SNP) | VAF 20/65 reads (31%) | catalogued as COSV100222057, COSV60697495; called by muse, mutect2, varscan2
- PIGG | c.2731C>T p.R911C (on ENST00000453061 / NM_001127178.3; = p.R903C on NM_017733.4) | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.157); catalogued as rs781165955, COSV56316138; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PPP1R9B | c.1282G>C p.E428Q | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.543); catalogued as COSV100380743; called by muse, mutect2, varscan2
- PRDM9 | c.2263C>T p.R755W | Missense Mutation (SNP) | VAF 44/125 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as rs375086019; called by muse, mutect2, varscan2
- PRKCG | c.1996G>A p.D666N | Missense Mutation (SNP) | VAF 48/132 reads (36%) | SIFT tolerated (0.45); PolyPhen benign (0.199); catalogued as rs373369366; called by muse, varscan2
- PRODH2 | c.655C>T p.R219W (on ENST00000301175; = p.R143W on NM_021232.2 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.424); catalogued as rs780775017, COSV56561175; called by muse, mutect2, varscan2
- PRPF4 | c.977C>T p.A326V (on ENST00000374198 / NM_001322267.2; = p.A327V on NM_004697.5) | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.714); catalogued as rs373783471; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PRR14 | c.412G>C p.E138Q | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.447); catalogued as COSV54913448; called by muse, mutect2, varscan2
- PTPRK | c.280C>T p.Q94* | Nonsense Mutation (SNP) | VAF 6/34 reads (18%) | catalogued as COSV100951273; called by muse, mutect2, varscan2
- RFX6 | c.1040G>A p.R347K | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.971); catalogued as COSV60583724; called by muse, mutect2, varscan2
- RMND1 | c.1159G>A p.D387N | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.301); catalogued as rs372096369, COSV60550260; called by muse, mutect2, varscan2
- RNF157 | c.272G>A p.R91Q | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs201739916, COSV53943416; called by muse, mutect2, varscan2
- SERPINA7 | c.192G>C p.K64N | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.267); catalogued as COSV100568360; called by muse, mutect2, varscan2
- SLC25A52 | c.88G>A p.D30N (on ENST00000672005; = p.D20N on NM_001034172.4) | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as COSV99329624; called by muse, mutect2, varscan2
- SLC4A4 | c.1563A>T p.Q521H (on ENST00000264485 / NM_001098484.3; = p.Q477H on NM_003759.4) | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99140491; called by mutect2, varscan2
- SLITRK2 | c.911C>T p.P304L | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.034); catalogued as rs782377976, COSV59423378; called by muse, mutect2, varscan2
- SLITRK2 | c.1887C>A p.F629L | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV59422958; called by muse, mutect2, varscan2
- SNX2 | c.1509G>A p.Q503= | Splice Region (SNP) | VAF 18/61 reads (30%) | catalogued as COSV101075717; called by muse, mutect2, varscan2
- SPTBN2 | c.2215C>T p.R739C | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.534); catalogued as rs376230007; called by muse, mutect2
- SYNJ2 | c.2315G>A p.G772E | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100840331; called by muse, mutect2, varscan2
- TFR2 | c.89G>A p.R30Q | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs750603454, COSV99355609; called by muse, mutect2, varscan2
- TGS1 | c.1866G>T p.K622N | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.218); catalogued as COSV99485468; called by muse, mutect2, varscan2
- THNSL2 | c.1150G>A p.E384K | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.528); catalogued as COSV100147521; called by muse, mutect2, varscan2
- TMEM156 | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.136); catalogued as COSV100756061; called by muse, mutect2
- TRIO | c.2340C>G p.I780M | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.311); catalogued as rs1312892908, COSV60085868; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TRIP12 | c.1600C>T p.Q534* | Nonsense Mutation (SNP) | VAF 12/45 reads (27%) | catalogued as COSV99390486; called by muse, mutect2, varscan2
- UBE2O | c.3155C>T p.T1052I | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.168); catalogued as COSV100039404; called by muse, mutect2, varscan2
- UROC1 | c.1745G>A p.R582H | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758929808, COSV52037733; called by muse, mutect2, varscan2
- USH2A | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV56339478; called by muse, mutect2, varscan2
- USP1 | c.905C>G p.S302* | Nonsense Mutation (SNP) | VAF 17/60 reads (28%) | catalogued as COSV100375253; called by muse, mutect2, varscan2
- UTP20 | c.604G>C p.D202H | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99881843; called by muse, mutect2, varscan2
- VAT1L | c.16G>A p.V6M | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.043); catalogued as rs1302290117, COSV56826523; called by muse, mutect2, varscan2
- VSTM4 | c.505G>A p.E169K | Missense Mutation (SNP) | VAF 38/160 reads (24%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV60529492; called by muse, mutect2, varscan2
- VWCE | c.2350C>T p.P784S | Missense Mutation (SNP) | VAF 39/67 reads (58%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.601); catalogued as COSV100075942; called by muse, mutect2, varscan2
- ZNF521 | c.1060G>A p.V354M | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.044); catalogued as rs140504840; called by muse, mutect2, varscan2
- ZNF592 | c.401C>T p.P134L | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.899); catalogued as COSV100245923; called by muse, mutect2, varscan2
- ZNF594 | c.2215G>C p.E739Q | Missense Mutation (SNP) | VAF 8/85 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.072); catalogued as COSV101280508; called by muse, mutect2, varscan2
- ZNF776 | c.572C>T p.S191L | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.23); catalogued as COSV100414224; called by muse, mutect2, varscan2
- LEXM | c.247_249del p.K83del | In Frame Del (DEL) | VAF 16/69 reads (23%) | called by pindel, varscan2
- MRM1 | c.839G>T p.R280L | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ABCA2 | c.4248G>A p.E1416= (on ENST00000614293; = p.E1386= on NM_001606.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 20/44 reads (45%) | catalogued as rs1230047931, COSV99687852; called by muse, mutect2, varscan2
- ADAMTS6 | c.3138C>G p.L1046= | Silent (SNP) | VAF 6/54 reads (11%) | catalogued as COSV100068436; called by muse, mutect2, varscan2
- ARFGEF3 | c.744G>A p.L248= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as COSV99293863; called by mutect2, varscan2
- ARHGAP44 | c.2022G>A p.P674= | Silent (SNP) | VAF 15/48 reads (31%) | catalogued as rs368805662; called by muse, varscan2
- BCL11A | c.1842G>A p.A614= (on ENST00000335712 / NM_001365609.1; = p.A648= on NM_018014.4) | Silent (SNP) | VAF 5/24 reads (21%) | catalogued as COSV59633100; called by muse, mutect2, varscan2
- CDHR2 | c.3168G>A p.P1056= | Silent (SNP) | VAF 11/30 reads (37%) | catalogued as rs267600559, COSV56142793; called by muse, mutect2, varscan2
- CDK2AP2 | c.159G>A p.P53= | Silent (SNP) | VAF 15/63 reads (24%) | catalogued as COSV100039422; called by muse, mutect2, varscan2
- CHST4 | c.222C>T p.P74= | Silent (SNP) | VAF 15/40 reads (38%) | catalogued as rs781070454, COSV58296376, COSV58298348; called by muse, mutect2, varscan2
- DNAH5 | c.10288T>C p.L3430= | Silent (SNP) | VAF 7/35 reads (20%) | catalogued as rs1356696172, COSV99450893; called by muse, mutect2, varscan2
- EXOC4 | c.1779G>C p.L593= | Silent (SNP) | VAF 9/44 reads (20%) | catalogued as COSV99554337; called by muse, mutect2, varscan2
- FBXO47 | c.711G>A p.L237= | Silent (SNP) | VAF 8/48 reads (17%) | catalogued as COSV100960756; called by muse, mutect2, varscan2
- FMNL1 | c.183C>T p.N61= | Silent (SNP) | VAF 17/55 reads (31%) | catalogued as rs763077404, COSV100056617; called by muse, mutect2, varscan2
- ITGA4 | c.123G>A p.A41= | Silent (SNP) | VAF 24/78 reads (31%) | catalogued as COSV99276458; called by muse, mutect2, varscan2
- JAG2 | c.3675G>A p.A1225= | Silent (SNP) | VAF 8/21 reads (38%) | catalogued as rs370520594; called by muse, mutect2
- KASH5 | c.723C>T p.S241= | Silent (SNP) | VAF 6/45 reads (13%) | catalogued as COSV101483458; called by muse, mutect2, varscan2
- KAT5 | c.1482G>A p.R494= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as COSV100383961; called by muse, mutect2, varscan2
- KSR2 | c.555G>A p.P185= | Silent (SNP) | VAF 20/75 reads (27%) | catalogued as rs373628463; called by muse, mutect2, varscan2
- LHX2 | c.267G>A p.S89= | Silent (SNP) | VAF 49/120 reads (41%) | catalogued as rs747785951, COSV101010064; called by muse, mutect2, varscan2
- MAPK10 | c.156G>C p.V52= (on ENST00000359221 / NM_001351625.2; = p.V90= on NM_002753.5) | Silent (SNP) | VAF 5/94 reads (5%) | catalogued as COSV100174705; called by muse, mutect2
- MOCS1 | c.588C>T p.F196= | Silent (SNP) | VAF 18/72 reads (25%) | catalogued as COSV100418670; called by muse, mutect2, varscan2
- MYH7 | c.4836G>C p.L1612= | Silent (SNP) | VAF 10/58 reads (17%) | catalogued as COSV100806235; called by muse, mutect2, varscan2
- NELL1 | c.306G>A p.V102= | Silent (SNP) | VAF 13/54 reads (24%) | catalogued as COSV100122171; called by muse, mutect2, varscan2
- NKAPL | c.153C>T p.L51= | Silent (SNP) | VAF 18/66 reads (27%) | catalogued as COSV100642538; called by muse, mutect2, varscan2
- NSMCE3 | c.558C>T p.I186= | Silent (SNP) | VAF 14/38 reads (37%) | catalogued as COSV99722484; called by muse, mutect2, varscan2
- OR4K5 | c.918G>A p.L306= | Silent (SNP) | VAF 6/112 reads (5%) | catalogued as rs1156867667, COSV100262275; called by muse, mutect2
- PABPC1L | c.1842G>A p.P614= | Silent (SNP) | VAF 11/98 reads (11%) | catalogued as rs771610516, COSV99407917; called by muse, mutect2, varscan2
- PBRM1 | c.3453C>T p.L1151= (on ENST00000296302 / NM_001366071.2; = p.L1126= on NM_018313.5) | Silent (SNP) | VAF 11/60 reads (18%) | catalogued as COSV56291539, COSV99969305; called by muse, mutect2, varscan2
- PIP5K1C | c.1686G>A p.P562= | Silent (SNP) | VAF 8/23 reads (35%) | catalogued as rs755952972, COSV100095570; called by muse, mutect2, varscan2
- PLTP | c.162G>A p.L54= | Silent (SNP) | VAF 75/150 reads (50%) | catalogued as COSV100819100; called by muse, mutect2, varscan2
- PRAMEF20 | c.156G>C p.L52= | Silent (SNP) | VAF 14/248 reads (6%) | called by muse, mutect2
- RBM33 | c.583T>C p.L195= | Silent (SNP) | VAF 66/101 reads (65%) | catalogued as rs746240306, COSV99841286; called by muse, mutect2, varscan2
- SEPTIN1 | c.906G>A p.E302= (on ENST00000321367; = p.E255= on NM_052838.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 13/25 reads (52%) | catalogued as COSV58441897; called by muse, mutect2, varscan2
- SGCG | c.552C>T p.V184= | Silent (SNP) | VAF 8/76 reads (11%) | catalogued as COSV99523054; called by muse, mutect2, varscan2
- SH3TC2 | c.3363G>A p.A1121= | Silent (SNP) | VAF 12/53 reads (23%) | catalogued as rs547035706, COSV100101888; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SIGLEC1 | c.279C>T p.P93= | Silent (SNP) | VAF 41/62 reads (66%) | catalogued as rs376680303, COSV99167002; called by muse, mutect2, varscan2
- SMAD6 | c.1440C>T p.F480= | Silent (SNP) | VAF 3/10 reads (30%) | catalogued as COSV56594556; called by muse, mutect2
- SPATA31A1 | c.381C>T p.G127= | Silent (SNP) | VAF 14/131 reads (11%) | catalogued as rs1477791281; called by muse, mutect2
- SPEF2 | c.687C>T p.L229= | Silent (SNP) | VAF 14/44 reads (32%) | catalogued as rs374415067, COSV99214363; called by muse, mutect2, varscan2
- TFEC | c.961C>T p.L321= | Silent (SNP) | VAF 15/48 reads (31%) | catalogued as COSV99624639; called by muse, mutect2, varscan2
- TRAPPC11 | c.1500G>A p.L500= | Silent (SNP) | VAF 19/75 reads (25%) | catalogued as COSV58217604; called by muse, mutect2, varscan2
- USH2A | c.1932T>C p.D644= | Silent (SNP) | VAF 30/87 reads (34%) | catalogued as rs1553326993, COSV100237033; called by muse, mutect2, varscan2
- ZNF33B | c.1200C>T p.L400= | Silent (SNP) | VAF 19/64 reads (30%) | catalogued as rs1297158987, COSV63942260; called by muse, mutect2, varscan2
- ZNF570 | c.1383G>A p.Q461= | Silent (SNP) | VAF 10/66 reads (15%) | catalogued as COSV100356223; called by muse, mutect2, varscan2
- EFNA4 | c.*114G>T | 3'UTR (SNP) | VAF 5/46 reads (11%) | catalogued as COSV100699663; called by muse, mutect2, varscan2
- IGFN1 | c.1242-94G>A | Intron (SNP) | VAF 22/47 reads (47%) | catalogued as COSV99812693; called by muse, mutect2, varscan2
- MFSD4B | c.*25C>T | 3'UTR (SNP) | VAF 6/26 reads (23%) | catalogued as rs777974519, COSV100920600; called by muse, mutect2, varscan2
- ZNF578 | chr19:52451211 C>T | 5'Flank (SNP) | VAF 11/76 reads (14%) | catalogued as COSV56520606; called by muse, mutect2, varscan2
